Somatic mutation profile of tumor specimen MP2PRT-PANWUT-TMP1-A (aliquot MP2PRT-PANWUT-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANWUT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,237 days).
Specimen MP2PRT-PANWUT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6313bf2b-35de-4d36-88e3-26061a776995.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANWUT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANWUT-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e09dab76-11c5-47d9-867b-acef633f7079

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZBTB42 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 276/759 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557164398; called by muse, mutect2, varscan2
- ETV6 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 43/377 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEPH | c.1585G>C p.A529P (on ENST00000343002; = p.A262P on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/506 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2
- HUWE1 | c.7141G>A p.V2381M | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- XBP1 | c.507_508insAGAGGCAGCACTCAGACTA p.A171Gfs*222 | Frame Shift Ins (INS) | VAF 106/311 reads (34%) | called by mutect2, varscan2
- MAGEB17 | c.342C>T p.G114= | Silent (SNP) | VAF 100/491 reads (20%) | catalogued as rs1432806844; called by muse, mutect2, varscan2
